Somatic mutation profile of tumor specimen C3L-06340-02 (aliquot CPT0362190009) from CPTAC case C3L-06340, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 60.1 years (21,944 days).
Specimen C3L-06340-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a9d5bd7-4479-450b-9fb7-70df82d41c29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06340-31 (Blood Derived Normal), aliquot CPT0362280002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cfbf7c4-67f1-458b-8923-21b3a46d781b

The open-access MAF lists 1,264 somatic variants for this specimen: 797 protein-altering or splice-affecting, 425 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 738, Silent 425, Nonsense Mutation 39, Intron 27, Splice Region 9, Frame Shift Del 7, 3'UTR 7, 5'Flank 3, Splice Site 2, RNA 2, 5'UTR 2, 3'Flank 1.

Variants (750 of 1,264; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/294 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- A2ML1 | c.3398A>G p.N1133S | Missense Mutation (SNP) | VAF 59/413 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.079); catalogued as rs763783506, COSV55285945, COSV55298506; called by muse, mutect2, varscan2
- ABCA1 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 63/397 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.011); catalogued as rs1250370138; called by muse, mutect2, varscan2
- ABCA7 | c.498G>A p.T166= | Splice Region (SNP) | VAF 83/384 reads (22%) | catalogued as rs369528566; called by muse, mutect2, varscan2
- ABCC8 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 58/417 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs765626111, COSV56856749; called by muse, mutect2, varscan2
- ABHD6 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 66/410 reads (16%) | catalogued as COSV55909353; called by muse, mutect2, varscan2
- AC021072.1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 70/445 reads (16%) | PolyPhen benign (0); catalogued as rs1208020744; called by muse, mutect2, varscan2
- AC099489.1 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 64/365 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as rs1336174529; called by muse, mutect2, varscan2
- ACOX3 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs762558027, COSV62711619; called by muse, mutect2, varscan2
- ACSL3 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62482527; called by muse, mutect2, varscan2
- ACSM4 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 37/385 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs752916520, COSV68067373, COSV68069242; called by muse, mutect2, varscan2
- ACTN1 | c.2269C>A p.H757N | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99517946; called by muse, mutect2, varscan2
- ACTN2 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 159/562 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs774252565, COSV63976993; called by muse, mutect2, varscan2
- ADAMDEC1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as rs1158215561, COSV56477584; called by muse, mutect2, varscan2
- ADAMTS12 | c.3136C>T p.P1046S | Missense Mutation (SNP) | VAF 89/566 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as rs1561140113, COSV100711654; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 51/366 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as rs763874259; called by muse, mutect2, varscan2
- ADGRL4 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV100875717; called by muse, mutect2, varscan2
- AGAP1 | c.2275G>A p.E759K (on ENST00000304032 / NM_001037131.3; = p.E706K on NM_014914.5) | Missense Mutation (SNP) | VAF 85/505 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs759890571, COSV58317509; called by muse, mutect2, varscan2
- AGL | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs375531470; called by muse, mutect2, varscan2
- AGTR1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 61/331 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100836960, COSV62558901; called by muse, mutect2, varscan2
- AHNAK2 | c.7904C>T p.S2635F | Missense Mutation (SNP) | VAF 90/596 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs763538508, COSV60919058; called by muse, mutect2, varscan2
- AKAP9 | c.11302G>A p.G3768R (on ENST00000359028; = p.G3744R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/554 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs200327385; called by muse, mutect2, varscan2
- ALK | c.1817G>A p.R606K | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.935); catalogued as COSV66567101; called by muse, mutect2, varscan2
- ALPK3 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 81/482 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs116593882; called by muse, mutect2, varscan2
- ANAPC7 | c.590G>T p.R197M | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV71444170; called by muse, mutect2, varscan2
- ANGPTL2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 53/506 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52234618; called by muse, mutect2, varscan2
- ANKK1 | c.2167G>A p.G723R | Missense Mutation (SNP) | VAF 62/379 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.255); catalogued as COSV58270065; called by muse, mutect2, varscan2
- ANO2 | c.2278C>T p.P760S (on ENST00000356134 / NM_001278597.3; = p.P764S on NM_001278596.3) | Missense Mutation (SNP) | VAF 58/460 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59037720; called by muse, mutect2, varscan2
- ANO2 | c.536G>A p.G179E (on ENST00000356134 / NM_001278597.3; = p.G183E on NM_001278596.3) | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59028169; called by muse, mutect2, varscan2
- ANO6 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 40/302 reads (13%) | catalogued as rs777838621; called by muse, mutect2, varscan2
- APOB | c.3055A>G p.T1019A | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV51937298, COSV99265943; called by muse, mutect2, varscan2
- APP | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.82); catalogued as rs201945946; called by muse, mutect2
- ARHGAP5 | c.2977C>T p.P993S | Missense Mutation (SNP) | VAF 52/381 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.093); catalogued as COSV61534839; called by muse, mutect2, varscan2
- ARIH2 | c.1478C>T p.T493I | Missense Mutation (SNP) | VAF 39/359 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.299); catalogued as rs771716485; called by muse, mutect2, varscan2
- ARMC3 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 58/348 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1176505640; called by muse, mutect2, varscan2
- ARMC9 | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 59/479 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs1301946383; called by muse, mutect2, varscan2
- ARMCX6 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 94/583 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.615); catalogued as rs781921761; called by muse, mutect2, varscan2
- ARPC2 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 26/285 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV55286257; called by muse, mutect2
- ASAP1 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 66/375 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.053); catalogued as rs768671699, COSV63050217; called by muse, mutect2, varscan2
- ATOH1 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 46/422 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.366); catalogued as rs1250650094, COSV60039078; called by muse, mutect2, varscan2
- ATP10D | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754586853, COSV56706682; called by muse, mutect2, varscan2
- ATP13A5 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100665034, COSV60869021; called by muse, mutect2, varscan2
- ATP1A4 | c.2147C>T p.A716V | Missense Mutation (SNP) | VAF 88/339 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as rs776439766; called by muse, mutect2, varscan2
- ATP8B1 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 53/344 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as CM096608, COSV99377146; called by muse, mutect2, varscan2
- ATRX | c.6178G>A p.E2060K | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as COSV64874506, COSV64884420; called by muse, mutect2, varscan2
- AUTS2 | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 68/595 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as rs770510009, COSV61395425; called by muse, mutect2, varscan2
- B4GALNT2 | c.1636C>T p.L546F | Missense Mutation (SNP) | VAF 73/432 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs1478982055, COSV55924872; called by muse, mutect2, varscan2
- B4GALNT3 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 63/470 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs751386462; called by muse, mutect2, varscan2
- BACE2 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 71/400 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV57743342; called by muse, mutect2, varscan2
- BBS12 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 74/444 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762349804; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4618G>A p.G1540R | Missense Mutation (SNP) | VAF 126/404 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1180157198, COSV63244121; called by muse, mutect2, varscan2
- C10orf120 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267602401; called by muse, mutect2, varscan2
- C10orf71 | c.3634G>A p.E1212K | Missense Mutation (SNP) | VAF 65/461 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1017960193; called by muse, mutect2, varscan2
- C10orf71 | c.3811C>T p.P1271S | Missense Mutation (SNP) | VAF 100/518 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as COSV100110667; called by muse, mutect2, varscan2
- C1orf210 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 134/630 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs774522331, COSV70682492; called by muse, mutect2, varscan2
- C8orf58 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs1345738333; called by muse, mutect2
- CALML5 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 81/491 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1179653441; called by muse, mutect2, varscan2
- CAPZA3 | c.510G>A p.W170* | Nonsense Mutation (SNP) | VAF 47/371 reads (13%) | catalogued as rs868010711, COSV56850834; called by muse, mutect2, varscan2
- CCDC130 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 219/686 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1426891020; called by muse, mutect2, varscan2
- CCDC168 | c.11157G>A p.M3719I | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV59421997; called by muse, mutect2, varscan2
- CCDC180 | c.2150G>A p.G717E | Missense Mutation (SNP) | VAF 82/461 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1227642989; called by muse, varscan2
- CCDC88B | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 63/355 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1221270155; called by muse, mutect2, varscan2
- CCR2 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.2); catalogued as rs1355689842; called by muse, mutect2, varscan2
- CD93 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 67/552 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV55668260; called by muse, mutect2, varscan2
- CDCP1 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs781414038, COSV99943934; called by muse, mutect2, varscan2
- CDRT1 | c.1187G>A p.R396K | Missense Mutation (SNP) | VAF 51/323 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99887485; called by muse, mutect2, varscan2
- CDX4 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 52/307 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65171688; called by muse, mutect2, varscan2
- CEP295 | c.7321C>T p.L2441F | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs558061169; called by muse, mutect2, varscan2
- CFAP47 | c.7009C>T p.P2337S | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66221233; called by muse, mutect2, varscan2
- CFH | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.881); catalogued as COSV66407548; called by muse, mutect2, varscan2
- CFTR | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs776162972; called by muse, mutect2, varscan2
- CHL1 | c.2210C>T p.S737F (on ENST00000397491 / NM_001253387.1; = p.S753F on NM_006614.4) | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs756724772; called by muse, mutect2, varscan2
- CHML | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 130/380 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.477); catalogued as COSV59366403; called by muse, mutect2, varscan2
- CHRM3 | c.960G>A p.W320* | Nonsense Mutation (SNP) | VAF 164/469 reads (35%) | catalogued as COSV55098042; called by muse, mutect2, varscan2
- CLEC14A | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV60563223, COSV60563655; called by muse, mutect2, varscan2
- CMYA5 | c.8465C>T p.S2822L | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV71407642; called by muse, mutect2, varscan2
- CNTNAP1 | c.1195C>T p.L399F | Missense Mutation (SNP) | VAF 74/579 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV52850530; called by muse, mutect2, varscan2
- CNTNAP3 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 39/244 reads (16%) | catalogued as COSV52663134; called by muse, mutect2, varscan2
- COBL | c.2111G>A p.G704D | Missense Mutation (SNP) | VAF 67/552 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375788304; called by muse, mutect2, varscan2
- COL11A1 | c.4439G>A p.G1480E | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759091446; called by muse, mutect2, varscan2
- COL21A1 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 60/397 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as rs868548222; called by muse, mutect2, varscan2
- COL5A1 | c.3304G>A p.G1102R | Missense Mutation (SNP) | VAF 76/511 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65668809; called by muse, mutect2, varscan2
- COMMD10 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768965375; called by muse, mutect2, varscan2
- CRAMP1 | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV51961831; called by muse, mutect2, varscan2
- CRISP3 | c.139C>T p.P47S (on ENST00000371159 / NM_001368123.1; = p.P29S on NM_006061.4) | Missense Mutation (SNP) | VAF 48/377 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.259); catalogued as COSV53821303; called by muse, mutect2, varscan2
- CRYBA4 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as COSV99081172; called by muse, mutect2, varscan2
- CSMD1 | c.9634C>T p.P3212S (on ENST00000520002; = p.P3211S on NM_033225.6) | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1201213860; called by muse, mutect2, varscan2
- CSMD1 | c.8024G>A p.R2675Q (on ENST00000520002; = p.R2674Q on NM_033225.6) | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs775089714, COSV100153884, COSV59332663; called by muse, mutect2, varscan2
- CSMD3 | c.10964G>A p.R3655K (on ENST00000297405 / NM_001363185.1; = p.R3486K on NM_052900.3) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52116881; called by muse, varscan2
- CSTF2 | c.1395G>A p.M465I | Missense Mutation (SNP) | VAF 92/566 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs916018642; called by muse, mutect2, varscan2
- CTAGE6 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 125/737 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as rs1478651470; called by muse, mutect2, varscan2
- CYBB | c.339G>A p.A113= | Splice Region (SNP) | VAF 45/236 reads (19%) | catalogued as rs1389196969, CD105699, COSV66086259; called by muse, mutect2, varscan2
- CYP2C8 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs140481138, COSV100987881; called by muse, mutect2, varscan2
- CYP8B1 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 93/493 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs141302264, COSV60226578; called by muse, mutect2, varscan2
- DCAF8L2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.486); catalogued as COSV70548057; called by mutect2, varscan2
- DCC | c.2066G>A p.G689E | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs868536178; called by muse, mutect2, varscan2
- DCDC2C | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.039); catalogued as rs960798381; called by muse, mutect2, varscan2
- DERPC | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as rs1321881123; called by muse, mutect2, varscan2
- DLGAP2 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 42/714 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101421801; called by muse, mutect2
- DNAH11 | c.7051G>A p.D2351N | Missense Mutation (SNP) | VAF 34/508 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60982223; called by muse, mutect2
- DNAH7 | c.5870G>A p.R1957Q | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs200790432, COSV56760571; called by muse, mutect2, varscan2
- DNMT3A | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53038171, COSV53039274; called by muse, varscan2
- DOCK4 | c.843C>T p.I281= | Splice Region (SNP) | VAF 118/331 reads (36%) | catalogued as rs374605086; called by muse, varscan2
- DRC1 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 53/305 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs751715818, COSV55504688; called by muse, mutect2, varscan2
- DSEL | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 44/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59494361; called by muse, varscan2
- DSG1 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 53/416 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs561112685, COSV57133677; called by muse, mutect2, varscan2
- DTHD1 | c.824G>A p.G275E (on ENST00000456874; = p.G110E on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); catalogued as rs770256085; called by muse, mutect2, varscan2
- EDC4 | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 77/537 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs781003773, COSV59302063; called by muse, mutect2, varscan2
- EIF2S3B | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 40/325 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1462805230; called by muse, mutect2, varscan2
- EMB | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV57480530; called by muse, mutect2, varscan2
- ENPP5 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV57908050; called by muse, mutect2, varscan2
- EPS15 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 93/359 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1435621895; called by muse, mutect2, varscan2
- ERBB3 | c.3647C>T p.S1216F | Missense Mutation (SNP) | VAF 77/497 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1281265231, COSV57253584; called by muse, mutect2, varscan2
- ERBB4 | c.2966G>A p.G989D | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs757867095; called by muse, mutect2, varscan2
- ERC2 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 57/504 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs750451019, COSV55603699; called by muse, mutect2, varscan2
- FAM107B | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 73/419 reads (17%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as COSV51686296; called by muse, mutect2, varscan2
- FAM118A | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 74/540 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53419731; called by muse, mutect2, varscan2
- FAT1 | c.7508A>G p.E2503G | Missense Mutation (SNP) | VAF 64/398 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71676399; called by muse, varscan2
- FGA | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 52/382 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV57396217; called by muse, mutect2, varscan2
- FGD1 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 57/366 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV64309379; called by muse, mutect2, varscan2
- FNDC7 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1361537939; called by muse, mutect2, varscan2
- FOXP2 | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 39/315 reads (12%) | catalogued as COSV63486238; called by muse, mutect2, varscan2
- FREM1 | c.4117G>A p.D1373N | Missense Mutation (SNP) | VAF 55/407 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772187059, COSV66522153; called by muse, mutect2, varscan2
- FRMPD1 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 71/443 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV66700481; called by muse, mutect2, varscan2
- FTHL17 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 94/576 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV63266373; called by muse, mutect2, varscan2
- FTMT | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 88/550 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs865797696, COSV58419985; called by muse, mutect2, varscan2
- FUNDC2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs1330499871; called by muse, mutect2, varscan2
- FUT10 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 70/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1243571063, COSV100161604, COSV59453570; called by muse, mutect2, varscan2
- GADL1 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56983287; called by muse, mutect2, varscan2
- GLRA1 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 79/440 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99199405; called by muse, mutect2, varscan2
- GPANK1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 66/460 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV63263866; called by muse, mutect2, varscan2
- GPKOW | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 88/445 reads (20%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.581); catalogued as COSV50245749; called by muse, mutect2, varscan2
- GPR156 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 98/579 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs775719509, COSV59942238; called by muse, mutect2, varscan2
- GTF2F1 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 66/426 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs781516730; called by muse, mutect2, varscan2
- HDGFL1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 84/640 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs1328773079; called by muse, mutect2, varscan2
- HIVEP2 | c.4667C>T p.S1556F | Missense Mutation (SNP) | VAF 78/412 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs771455500; called by muse, mutect2, varscan2
- HIVEP3 | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 125/624 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56015668; called by muse, mutect2, varscan2
- HOOK1 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 115/463 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.846); catalogued as rs906964084, COSV64618669; called by muse, mutect2, varscan2
- IFNA17 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 70/541 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.037); catalogued as rs565291074; called by muse, mutect2, varscan2
- IGF1R | c.3871G>A p.E1291K | Missense Mutation (SNP) | VAF 97/686 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as rs1279929438; called by muse, mutect2, varscan2
- IGFN1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 102/380 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs1458084402; called by muse, mutect2, varscan2
- IGHG3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 59/449 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.533); catalogued as rs587597693; called by muse, mutect2, varscan2
- IGHV3-66 | c.136T>C p.F46L | Missense Mutation (SNP) | VAF 57/474 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.47); catalogued as rs782018841; called by muse, mutect2, varscan2
- IL1RL1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 54/412 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV99294267; called by muse, varscan2
- IL36B | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 54/358 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.162); catalogued as rs755811144, COSV52084410; called by muse, varscan2
- IL7 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1563413800, COSV55675723; called by muse, mutect2, varscan2
- INPP5E | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs770456201; called by muse, mutect2, varscan2
- INPP5J | c.2446G>A p.G816R (on ENST00000331075 / NM_001284285.2; = p.G448R on NM_001002837.2) | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99311573; called by muse, mutect2, varscan2
- INTS6L | c.2534C>T p.S845F | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1556534583; called by muse, mutect2, varscan2
- IQCK | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs368454803; called by muse, mutect2, varscan2
- IQUB | c.827G>A p.R276K | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1388500153, COSV100226901; called by muse, mutect2, varscan2
- IRF6 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV65419049; called by muse, mutect2
- ITGA10 | c.3065C>T p.P1022L | Missense Mutation (SNP) | VAF 101/340 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs201498719, COSV65199055; called by muse, mutect2, varscan2
- JCAD | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 85/448 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV64758039; called by muse, mutect2, varscan2
- KCNH2 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 267/716 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.262); catalogued as CM139887, CM1511209; called by muse, mutect2, varscan2
- KCNIP4 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 73/356 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs548454366, COSV62845262; called by muse, mutect2, varscan2
- KCNT2 | c.2762G>A p.G921E | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV54071255; called by muse, mutect2, varscan2
- KCP | c.2210G>A p.R737Q (on ENST00000620378; = p.R797Q on NM_001366122.1) | Missense Mutation (SNP) | VAF 71/699 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs1248078581; called by muse, mutect2
- KEL | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 90/776 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV62335832; called by muse, mutect2, varscan2
- KIAA1217 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 92/440 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769073090, COSV56813347; called by muse, mutect2, varscan2
- KIF26B | c.3452C>T p.P1151L | Missense Mutation (SNP) | VAF 261/681 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs955347137, COSV63645175; called by muse, mutect2, varscan2
- KIF9 | c.1781G>A p.R594Q (on ENST00000265529 / NM_001377474.1; = p.R529Q on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/397 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs765763930, COSV55517710; called by muse, mutect2, varscan2
- KIR3DL1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 70/257 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.859); catalogued as rs1304651125; called by muse, mutect2, varscan2
- KLF18 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 54/445 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.691); catalogued as rs1038078826; called by muse, mutect2, varscan2
- KLHDC10 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 95/624 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); catalogued as COSV59050266; called by muse, mutect2, varscan2
- KLHL40 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 74/347 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs771203108, COSV55132986, COSV55137444; called by muse, mutect2, varscan2
- KMT2C | c.9283C>T p.P3095S | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1208081081, COSV104383872; called by muse, mutect2, varscan2
- KMT2C | c.9008G>A p.S3003N | Missense Mutation (SNP) | VAF 122/537 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51375435; called by muse, mutect2, varscan2
- KPRP | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 55/538 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64221524; called by muse, mutect2, varscan2
- KRT14 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 60/382 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99391115; called by muse, mutect2, varscan2
- KRT16 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 102/688 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs1133106, COSV56969291; called by muse, mutect2, varscan2
- KRT81 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 54/394 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59809168; called by muse, mutect2, varscan2
- KRT83 | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 64/368 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs774609094; called by muse, varscan2
- LAMB3 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs375951428; called by muse, mutect2
- LCA5 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs568193819, COSV63971388; called by muse, mutect2, varscan2
- LCT | c.2972C>T p.S991F | Missense Mutation (SNP) | VAF 80/423 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs758837934, COSV51553686; called by muse, mutect2, varscan2
- LIM2 | c.397G>A p.D133N (on ENST00000596399 / NM_001161748.2; = p.D175N on NM_030657.4) | Missense Mutation (SNP) | VAF 171/600 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs1321015329; called by muse, mutect2, varscan2
- LMNTD1 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV51451051; called by muse, mutect2, varscan2
- LRRC37A3 | c.3931C>T p.R1311C | Missense Mutation (SNP) | VAF 76/529 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs752685034, COSV58535521; called by muse, mutect2, varscan2
- LRRIQ3 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs1412767236; called by muse, mutect2, varscan2
- LRRN4 | c.1751G>A p.R584K | Missense Mutation (SNP) | VAF 167/685 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as rs868825408; called by muse, mutect2, varscan2
- LTBP2 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 85/654 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs1242987921; called by muse, mutect2, varscan2
- MACC1 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV60545684; called by muse, mutect2
- MAGEA11 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 92/568 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV60758789; called by muse, mutect2, varscan2
- MAGED2 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 98/576 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV54498378; called by muse, varscan2
- MAGEE2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 66/452 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267606512, COSV64898496; called by muse, mutect2, varscan2
- MAP3K15 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs1235750422, COSV58828617; called by muse, mutect2, varscan2
- MEFV | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 23/532 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1042945356, COSV54818489; called by muse, mutect2
- MIF4GD | c.655G>A p.E219K (on ENST00000325102 / NM_001370592.1; = p.E253K on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs754208867, COSV99821602; called by muse, mutect2, varscan2
- MMRN1 | c.2836C>T p.P946S | Missense Mutation (SNP) | VAF 63/328 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV53337632; called by muse, mutect2, varscan2
- MNX1 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 133/504 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs867541256; called by muse, mutect2, varscan2
- MORC4 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs140475018; called by muse, mutect2, varscan2
- MTMR11 | c.1597C>T p.P533S (on ENST00000439741 / NM_001145862.2; = p.P461S on NM_181873.3) | Missense Mutation (SNP) | VAF 118/453 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs1553767246; called by muse, mutect2, varscan2
- MUC12 | c.1292C>T p.S431L (on ENST00000379442; = p.S288L on NM_001164462.1) | Missense Mutation (SNP) | VAF 79/730 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs1198721514, COSV65186899; called by muse, mutect2, varscan2
- MUC12 | c.13433C>T p.S4478L (on ENST00000379442; = p.S4335L on NM_001164462.1) | Missense Mutation (SNP) | VAF 195/1216 reads (16%) | SIFT deleterious, low confidence (0); catalogued as rs763815483; called by muse, mutect2, varscan2
- MUC16 | c.8371G>A p.G2791R | Missense Mutation (SNP) | VAF 57/305 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1412242014; called by muse, mutect2, varscan2
- MUSK | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 60/414 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as rs754275653, COSV51891534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MXRA5 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 68/551 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866233220, COSV54222468; called by muse, mutect2, varscan2
- MYH11 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 73/414 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs112553563, COSV55558251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 72/359 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs756281353, COSV55438538, COSV99820030; called by muse, mutect2, varscan2
- MYO1G | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 154/559 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1209756872; called by muse, mutect2, varscan2
- MYO9A | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 58/593 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs1268939311; called by muse, mutect2
- MYO9A | c.2908C>T p.P970S | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV61856797; called by muse, mutect2, varscan2
- NBEA | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868169550, COSV59765311; called by muse, mutect2, varscan2
- NCF2 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 129/497 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as COSV62316051; called by muse, mutect2, varscan2
- NCKAP5 | c.4628G>A p.G1543E | Missense Mutation (SNP) | VAF 55/372 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1228881406, COSV100494820; called by muse, mutect2, varscan2
- NCKAP5 | c.3056G>A p.R1019Q | Missense Mutation (SNP) | VAF 81/518 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.514); catalogued as rs377381048; called by muse, mutect2, varscan2
- NCOA6 | c.5567G>A p.G1856E | Missense Mutation (SNP) | VAF 116/442 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.998); catalogued as COSV62868278; called by muse, mutect2, varscan2
- NEXMIF | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 61/398 reads (15%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); catalogued as rs774834561; ClinVar: uncertain significance; called by muse, varscan2
- NFATC1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 74/505 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.891); catalogued as rs775904780; called by muse, mutect2, varscan2
- NHS | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 69/562 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as rs1377194594; called by muse, mutect2, varscan2
- NINL | c.2626G>A p.G876R | Missense Mutation (SNP) | VAF 110/572 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV54009894; called by muse, mutect2, varscan2
- NLRP13 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 109/378 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs544413027, COSV61619947; called by muse, mutect2, varscan2
- NLRP14 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV55073136; called by muse, mutect2, varscan2
- NUP160 | c.2389C>T p.Q797* | Nonsense Mutation (SNP) | VAF 37/224 reads (17%) | catalogued as rs1453013313, COSV65854253; called by muse, mutect2, varscan2
- NWD1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 153/493 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs771904053, COSV100342910, COSV100343724; called by muse, mutect2, varscan2
- OLAH | c.736G>A p.E246K (on ENST00000378228 / NM_001039702.3; = p.E299K on NM_018324.3) | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as rs1343008369, COSV62252277; called by muse, mutect2, varscan2
- OPRD1 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 84/281 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs1394263354, COSV52383053; called by muse, mutect2, varscan2
- OPRM1 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 95/473 reads (20%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); catalogued as rs201750403; called by muse, mutect2, varscan2
- OR10G6 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.123); catalogued as rs1201425911; called by muse, mutect2, varscan2
- OR13C8 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs867707776, COSV100622952; called by muse, mutect2, varscan2
- OR1L1 | c.272G>A p.G91E (on ENST00000373686; = p.G41E on NM_001005236.3) | Missense Mutation (SNP) | VAF 79/412 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390819796, COSV58935923; called by muse, mutect2, varscan2
- OR2A2 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 47/540 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs139387901, COSV68872305; called by muse, mutect2
- OR2H1 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 64/463 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV65810498; called by muse, mutect2, varscan2
- OR2K2 | c.140C>T p.S47F (on ENST00000374428; = p.S18F on NM_205859.2) | Missense Mutation (SNP) | VAF 61/334 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV57016017; called by muse, mutect2, varscan2
- OR2T27 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs747078103, COSV61280506; called by muse, mutect2
- OR4A16 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 85/464 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.082); catalogued as rs575051490, COSV59042137; called by muse, mutect2, varscan2
- OR4C16 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 87/478 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1565052193, COSV58942866; called by muse, mutect2, varscan2
- OR51B5 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV56176328; called by muse, mutect2, varscan2
- OR51T1 | c.913A>G p.M305V | Missense Mutation (SNP) | VAF 61/344 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs774525875; called by muse, mutect2, varscan2
- OR5AC2 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376947224, COSV100684336; called by muse, varscan2
- OR5L2 | c.893A>G p.N298S | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1205446612; called by muse, mutect2, varscan2
- OR5R1 | c.857A>T p.N286I | Missense Mutation (SNP) | VAF 57/350 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56572059; called by muse, mutect2, varscan2
- OR7D2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 106/404 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV100712982; called by muse, mutect2, varscan2
- OR7G3 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 172/514 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs144765135, COSV100555607; called by muse, mutect2, varscan2
- OR7G3 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 173/453 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as rs1182369624; called by muse, mutect2
- OR8S1 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 86/495 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.855); catalogued as COSV100043570; called by muse, mutect2, varscan2
- OR9K2 | c.871C>T p.P291S (on ENST00000305377; = p.P269S on NM_001005243.1) | Missense Mutation (SNP) | VAF 44/332 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as rs148051420; called by muse, mutect2, varscan2
- OTOGL | c.4117G>A p.E1373K (on ENST00000547103; = p.E1364K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755276225, COSV72007277; called by muse, mutect2, varscan2
- P3H2 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV60019137; called by muse, mutect2, varscan2
- PAX7 | c.1388G>A p.G463D | Missense Mutation (SNP) | VAF 82/654 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.24); catalogued as rs758921663, COSV100946761; called by muse, mutect2, varscan2
- PAX8 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 71/496 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1357839077; called by muse, mutect2, varscan2
- PCDH11X | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs773201452; called by muse, mutect2, varscan2
- PCDH15 | c.3115G>A p.E1039K | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as rs866090744, COSV100216209; called by muse, mutect2, varscan2
- PCDHA10 | c.1835C>T p.S612L | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as rs782327077; called by muse, mutect2, varscan2
- PCDHB14 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 66/388 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.03); catalogued as COSV53391048; called by muse, varscan2
- PCDHB7 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 76/405 reads (19%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.055); catalogued as rs267600426, COSV50753987; called by muse, mutect2
- PCLO | c.13493A>T p.K4498I | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100429613; called by muse, mutect2, varscan2
- PCSK1 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 66/516 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs140899352; called by muse, mutect2, varscan2
- PDCL3 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs750858703, COSV51808903; called by muse, mutect2, varscan2
- PDGFRA | c.3216G>A p.M1072I | Missense Mutation (SNP) | VAF 75/489 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV57267355; called by muse, mutect2, varscan2
- PDZD7 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 68/396 reads (17%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1225550811; called by muse, mutect2, varscan2
- PEG3 | c.3634C>T p.R1212C | Missense Mutation (SNP) | VAF 138/470 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1452885066, COSV55645813; called by muse, varscan2
- PEX14 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 96/284 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as rs1250012399; called by muse, mutect2, varscan2
- PGAP1 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV61324993; called by muse, mutect2, varscan2
- PHF2 | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 53/407 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.436); catalogued as rs750048636, COSV63680980; called by muse, mutect2, varscan2
- PI4KA | c.4776C>T p.F1592= | Splice Region (SNP) | VAF 57/319 reads (18%) | catalogued as rs138845425; called by muse, mutect2, varscan2
- PIK3C2G | c.3064C>T p.R1022C (on ENST00000676171; = p.R981C on NM_004570.5) | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as rs774333984, COSV56819263; called by muse, mutect2, varscan2
- PIK3CG | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 84/686 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as COSV63247987; called by muse, mutect2, varscan2
- PIP | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 48/400 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs1303868602, COSV52120810; called by muse, mutect2, varscan2
- PLCB1 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 66/289 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs780585750, COSV62057790; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCL1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 66/446 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780511339, COSV70844244; called by muse, varscan2
- PLEKHG6 | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 67/424 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs147609266; called by muse, mutect2, varscan2
- PLXDC2 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as rs768383816, COSV101022803; called by muse, mutect2, varscan2
- PLXND1 | c.1811C>T p.T604I | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as rs1329929321; called by muse, mutect2, varscan2
- PMEPA1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 109/711 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55693554; called by muse, mutect2, varscan2
- PNLDC1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs745935275, COSV51706726, COSV51706896; called by muse, mutect2, varscan2
- POM121 | c.1819C>T p.P607S (on ENST00000434423; = p.P342S on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/316 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs1332406067, COSV99987426; called by muse, mutect2, varscan2
- POM121L12 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 200/742 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as rs779399045, COSV68692489, COSV68693229; called by muse, mutect2, varscan2
- POMGNT2 | c.1144A>G p.M382V | Missense Mutation (SNP) | VAF 44/399 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1168495290; called by muse, mutect2, varscan2
- PPEF2 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1277441879; called by muse, mutect2, varscan2
- PPFIA2 | c.1391G>A p.R464K | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as COSV61021181; called by muse, mutect2, varscan2
- PPP4R3C | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs1346090516; called by muse, mutect2, varscan2
- PPP4R4 | c.2530G>A p.G844R | Missense Mutation (SNP) | VAF 76/472 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.372); catalogued as rs776455163; called by muse, mutect2, varscan2
- PREX2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866864487, COSV55780007; called by muse, mutect2, varscan2
- PREX2 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV55779029; called by muse, mutect2, varscan2
- PRR11 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 57/434 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51877837; called by mutect2, varscan2
- PRRG3 | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 85/547 reads (16%) | catalogued as COSV64850979; called by muse, mutect2, varscan2
- PRSS58 | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 68/730 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs781031779, COSV73488442; called by muse, mutect2
- PRUNE2 | c.5539G>A p.E1847K | Missense Mutation (SNP) | VAF 61/406 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1235737351, COSV65043949; called by muse, mutect2, varscan2
- PTGIS | c.1432C>A p.L478I | Missense Mutation (SNP) | VAF 151/497 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.162); catalogued as rs761195637, COSV54837695; called by muse, mutect2, varscan2
- PTPRA | c.1247C>T p.T416I | Missense Mutation (SNP) | VAF 119/505 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.179); catalogued as COSV53782083; called by muse, mutect2, varscan2
- PTPRC | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 96/337 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV61411347; called by muse, mutect2, varscan2
- PTPRD | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.054); catalogued as rs757922864, COSV61929535; called by muse, mutect2, varscan2
- PTPRD | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 83/531 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.281); catalogued as rs1354824749, COSV61928182; called by muse, mutect2
- PTPRF | c.2330C>T p.S777F | Missense Mutation (SNP) | VAF 116/530 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as rs767930658, COSV63445984; called by muse, mutect2, varscan2
- PTPRN2 | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 212/574 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.387); catalogued as rs780089062, COSV67021216; called by muse, mutect2, varscan2
- PWWP3B | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 78/526 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); catalogued as rs1329842665, COSV61800589; called by muse, mutect2, varscan2
- RAB19 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 70/702 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52044464; called by muse, mutect2, varscan2
- RAPGEF4 | c.2297G>A p.G766E | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs753221185, COSV99911054; called by muse, mutect2, varscan2
- RBMXL1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 132/617 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs375804050, COSV99556641; called by muse, mutect2, varscan2
- RGS18 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 126/459 reads (27%) | catalogued as COSV66509555; called by muse, mutect2, varscan2
- RGSL1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 30/409 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as COSV54253980; called by muse, mutect2
- RP1 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV55128929; called by muse, mutect2, varscan2
- RP1 | c.3899G>A p.G1300E | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99608136; called by muse, mutect2
- RXFP1 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.414); catalogued as rs751091154, COSV57050314; called by muse, mutect2, varscan2
- RXFP2 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs759652097, COSV53636271; called by muse, mutect2, varscan2
- RYR3 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs1160628325, COSV66794064; called by muse, mutect2, varscan2
- SACS | c.2806C>T p.Q936* | Nonsense Mutation (SNP) | VAF 79/293 reads (27%) | catalogued as rs61978562; called by muse, mutect2, varscan2
- SALL1 | c.3839G>A p.G1280E | Missense Mutation (SNP) | VAF 61/415 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51764037; called by muse, mutect2, varscan2
- SALL1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 85/451 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs372343403; called by muse, mutect2, varscan2
- SAMD9 | c.4730C>T p.S1577F | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV66072884; called by muse, mutect2, varscan2
- SCN1A | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV57666249; called by muse, mutect2, varscan2
- SCRT2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 113/688 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55730281; called by muse, mutect2, varscan2
- SETD1A | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 74/431 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs747410617, COSV99353455; called by muse, mutect2, varscan2
- SF3B3 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as rs1275165584; called by muse, mutect2, varscan2
- SGSH | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 64/390 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.797); catalogued as rs1453784971; called by muse, mutect2, varscan2
- SH3BP4 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 79/499 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs996292773, COSV100749325; called by muse, mutect2, varscan2
- SHISA6 | c.1154C>G p.P385R (on ENST00000409168 / NM_001173461.1; = p.P436R on NM_207386.4) | Missense Mutation (SNP) | VAF 49/424 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV69396020; called by muse, mutect2, varscan2
- SIPA1L1 | c.2288C>T p.S763F | Missense Mutation (SNP) | VAF 46/333 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62170856; called by muse, mutect2, varscan2
- SLC12A8 | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100103118, COSV100103282; called by muse, mutect2, varscan2
- SLC15A2 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 51/323 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV55196581; called by muse, mutect2, varscan2
- SLC27A2 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as rs1485894674; called by muse, mutect2, varscan2
- SLC30A3 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV51984360; called by muse, mutect2
- SLC35F3 | c.402G>A p.R134= (on ENST00000366617 / NM_001300845.1; = p.R203= on NM_173508.4) | Splice Region (SNP) | VAF 30/352 reads (9%) | catalogued as COSV100784903; called by muse, mutect2
- SLC36A2 | c.1237G>C p.V413L | Missense Mutation (SNP) | VAF 89/507 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as COSV58862721; called by muse, mutect2, varscan2
- SLC38A4 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56964792; called by muse, mutect2, varscan2
- SLC49A4 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs763882530, COSV53746340; called by muse, mutect2, varscan2
- SLC4A8 | c.2779C>T p.R927C | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302713555, COSV60647696; called by muse, mutect2, varscan2
- SLC6A19 | c.1165C>T p.L389F | Missense Mutation (SNP) | VAF 53/369 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV100443701; called by muse, mutect2, varscan2
- SLCO4C1 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV60520201; called by muse, mutect2
- SLFN5 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200108679, COSV55479923; called by muse, mutect2, varscan2
- SLIT3 | c.3041G>A p.G1014E | Missense Mutation (SNP) | VAF 67/400 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV60614437; called by muse, mutect2, varscan2
- SLITRK4 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 65/434 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1477051104, COSV62025349; called by muse, mutect2, varscan2
- SMYD1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 46/453 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs770519021, COSV70225276; called by muse, mutect2
- SNX8 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 64/634 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1192804716, COSV56127369; called by muse, mutect2
- SORCS3 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63813400; called by muse, mutect2, varscan2
- SP140 | c.1499G>A p.R500K | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs202247799, COSV100614156; called by muse, mutect2, varscan2
- SPEG | c.8714C>T p.S2905F | Missense Mutation (SNP) | VAF 68/447 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1394564669; called by muse, mutect2, varscan2
- SPTA1 | c.5702C>T p.S1901F | Missense Mutation (SNP) | VAF 64/399 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as rs1376688572, COSV63759511; called by muse, mutect2, varscan2
- STAG2 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV54354453; called by muse, mutect2, varscan2
- STAP2 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55699214; called by muse, mutect2, varscan2
- SYN2 | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV70285887; called by muse, mutect2, varscan2
- TAS2R39 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 58/512 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71471030; called by muse, mutect2, varscan2
- TBC1D3B | c.72G>A p.K24= | Splice Region (SNP) | VAF 35/519 reads (7%) | catalogued as rs1435418067; called by muse, mutect2
- TBPL2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1370123558, COSV55972166; called by muse, mutect2, varscan2
- TCL1B | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 72/486 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.243); catalogued as rs1301280694; called by muse, varscan2
- TECPR1 | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 75/665 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs770394923; called by muse, mutect2, varscan2
- TEKT4 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 71/349 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as rs782176752; called by muse, mutect2, varscan2
- TENT4B | c.1987C>T p.R663C (on ENST00000561678 / NM_001365323.2; = p.R648C on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.201); catalogued as rs574661923, COSV62546332; called by muse, mutect2
- TENT5C | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 53/330 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65616200; called by muse, mutect2, varscan2
- TGIF2LX | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 80/455 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); catalogued as rs756446097, COSV52213962; called by muse, mutect2, varscan2
- TGM1 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 73/506 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as COSV99252795; called by muse, mutect2, varscan2
- THOC2 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs1556302160, COSV55540286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THRB | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 59/437 reads (14%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.977); catalogued as COSV54981903; called by muse, mutect2, varscan2
- TIMD4 | c.402C>T p.A134= | Splice Region (SNP) | VAF 57/347 reads (16%) | catalogued as rs1327345818; called by muse, mutect2, varscan2
- TIMELESS | c.3275G>A p.R1092Q | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as rs201006811; called by muse, mutect2
- TKTL2 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 51/372 reads (14%) | catalogued as COSV99761803; called by muse, mutect2, varscan2
- TLR1 | c.1891C>T p.L631F | Missense Mutation (SNP) | VAF 60/437 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as rs1259424613; called by muse, mutect2, varscan2
- TMCC2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1223978488; called by muse, varscan2
- TMEM196 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 121/657 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs753809570, COSV101337537, COSV68255396; called by muse, mutect2, varscan2
- TMPRSS9 | c.2396C>T p.P799L (on ENST00000648592; = p.P765L on NM_182973.2) | Missense Mutation (SNP) | VAF 85/527 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs201404482; called by muse, mutect2, varscan2
- TNNI3K | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.98); catalogued as COSV53946136; called by muse, mutect2, varscan2
- TNR | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 147/518 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as rs531733667, COSV54868765; called by muse, mutect2, varscan2
- TP63 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.885); catalogued as rs754361670, COSV53209193, COSV53218266; called by muse, mutect2, varscan2
- TPTE | c.1138G>A p.E380K (on ENST00000618007 / NM_199261.4; = p.E362K on NM_199259.4) | Missense Mutation (SNP) | VAF 23/296 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs781489069; called by muse, mutect2
- TRANK1 | c.6070G>A p.E2024K | Missense Mutation (SNP) | VAF 72/452 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs776681695, COSV57143953; called by muse, mutect2, varscan2
- TRAP1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs372386909; called by muse, mutect2, varscan2
- TREH | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs573517484; called by muse, mutect2, varscan2
- TRPC7 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 77/484 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1561733109, COSV61454469; called by muse, mutect2, varscan2
- TSSK6 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 70/560 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs761157837; called by muse, mutect2, varscan2
- TTN | c.80818G>A p.E26940K (on ENST00000591111; = p.E19516K on NM_003319.4) | Missense Mutation (SNP) | VAF 51/353 reads (14%) | PolyPhen benign (0.033); catalogued as COSV60003318; called by muse, mutect2, varscan2
- TTN | c.80246C>T p.S26749F (on ENST00000591111; = p.S19325F on NM_003319.4) | Missense Mutation (SNP) | VAF 67/461 reads (15%) | PolyPhen probably damaging (0.912); catalogued as rs267599032, COSV59897268; called by muse, mutect2, varscan2
- TTN | c.46466G>A p.G15489E (on ENST00000591111; = p.G8065E on NM_003319.4) | Missense Mutation (SNP) | VAF 61/344 reads (18%) | PolyPhen probably damaging (1); catalogued as COSV59934282; called by muse, mutect2, varscan2
- TTN | c.36803G>A p.G12268E (on ENST00000591111; = p.G4844E on NM_003319.4) | Missense Mutation (SNP) | VAF 42/315 reads (13%) | PolyPhen probably damaging (0.912); catalogued as COSV60379134; called by muse, mutect2, varscan2
- TTN | c.23075C>T p.S7692F (on ENST00000591111; = p.S6765F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/498 reads (16%) | PolyPhen possibly damaging (0.654); catalogued as rs759900757, COSV60185238; called by muse, mutect2, varscan2
- TTN | c.22666G>A p.D7556N (on ENST00000591111; = p.D6629N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/252 reads (16%) | PolyPhen benign (0.012); catalogued as rs753929851, COSV60168326; called by muse, mutect2, varscan2
- UGT1A5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs1357928110, COSV59380995; called by muse, mutect2, varscan2
- UGT2B17 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1157508518; called by muse, mutect2, varscan2
- UNC13C | c.4277C>T p.S1426L | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as rs1177997616, COSV52883187; called by muse, mutect2, varscan2
- USP7 | c.2185G>A p.D729N | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100784031, COSV61216860; called by muse, mutect2, varscan2
- VCAN | c.7135G>A p.E2379K | Missense Mutation (SNP) | VAF 57/366 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV54118692; called by muse, mutect2, varscan2
- VPS13D | c.7364C>T p.S2455F | Missense Mutation (SNP) | VAF 19/410 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs1234875663, COSV50625216; called by muse, mutect2
- VRTN | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 102/625 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99832488; called by muse, mutect2, varscan2
- WDR72 | c.2941C>T p.Q981* | Nonsense Mutation (SNP) | VAF 48/302 reads (16%) | catalogued as rs1205862024, COSV64746275, COSV64753946; called by muse, mutect2, varscan2
- WDR88 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 135/471 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as rs770635793, COSV100866433, COSV63451247; called by muse, mutect2, varscan2
- WNT11 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 97/604 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as rs762919465; called by muse, mutect2, varscan2
- XDH | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199658065; called by muse, mutect2
- XIRP2 | c.5015C>T p.S1672F (on ENST00000628543; = p.S1847F on NM_152381.6) | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267598983; called by muse, mutect2, varscan2
- YLPM1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 63/292 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as rs760520326; called by muse, mutect2, varscan2
- ZAN | c.3008C>T p.P1003L | Missense Mutation (SNP) | VAF 87/943 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as rs868049605, COSV61807593; called by muse, mutect2
- ZBTB41 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV66359884; called by muse, mutect2, varscan2
- ZCCHC12 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 64/389 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs1212891619, COSV59571293; called by muse, mutect2, varscan2
- ZDBF2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 48/373 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.103); catalogued as rs779996852, COSV65621430, COSV65629627; called by muse, mutect2, varscan2
- ZFYVE27 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs145746084; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- ZMYM3 | c.314G>A p.W105* | Nonsense Mutation (SNP) | VAF 96/642 reads (15%) | catalogued as COSV100078303; called by muse, mutect2, varscan2
- ZNF117 | c.470G>A p.R157K | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.112); catalogued as rs371560994, COSV51426170; called by muse, mutect2, varscan2
- ZNF282 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 126/502 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1408813924; called by muse, mutect2, varscan2
- ZNF395 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 67/347 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as rs1186856945; called by muse, mutect2, varscan2
- ZNF492 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as rs763514609; called by muse, mutect2, varscan2
- ZNF516 | c.2866C>T p.P956S | Missense Mutation (SNP) | VAF 72/472 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs747195084; called by muse, mutect2, varscan2
- ZNF536 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 131/404 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.023); catalogued as rs1229570147, COSV62822670; called by muse, mutect2, varscan2
- ZNF804A | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV56452694; called by muse, mutect2, varscan2
- ZNF831 | c.3347C>T p.S1116L | Missense Mutation (SNP) | VAF 170/600 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1191218602, COSV64044887; called by muse, mutect2, varscan2
- ZNF92 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as COSV60874526; called by muse, mutect2, varscan2
- ZNF99 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as COSV68054672; called by muse, mutect2, varscan2
- ZP2 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs761155186; called by muse, mutect2, varscan2
- ZP4 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 78/356 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs149320005, COSV63912403, COSV63913550; called by muse, mutect2, varscan2
- AATF | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 83/418 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- ABCB4 | c.2323A>T p.T775S | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- ABCC6 | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 66/498 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM15 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 139/552 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- ADAMTS12 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ADAMTS18 | c.1277C>A p.T426K | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADGRA1 | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 51/345 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGBL1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 70/562 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2
- AHCY | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 84/322 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- AJAP1 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 204/649 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- AKNAD1 | c.2225G>A p.G742D | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AKNAD1 | c.2224G>A p.G742S | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.188); called by muse, varscan2
- ALMS1 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 69/431 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ALS2CL | c.787G>A p.G263S | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK3 | c.10676C>T p.S3559L | Missense Mutation (SNP) | VAF 57/346 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ANKAR | c.3494T>C p.I1165T | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- ANKRD35 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 98/271 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO2 | c.1222C>T p.P408S (on ENST00000356134 / NM_001278597.3; = p.P412S on NM_001278596.3) | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANO2 | c.1121C>T p.S374F (on ENST00000356134 / NM_001278597.3; = p.S378F on NM_001278596.3) | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP29 | c.2169A>T p.E723D | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP5 | c.3803T>C p.V1268A (on ENST00000345122 / NM_001030055.2; = p.V1267A on NM_001173.3) | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ARHGEF26 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 63/393 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARHGEF28 | c.4285G>A p.D1429N | Missense Mutation (SNP) | VAF 43/408 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- ARSF | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 100/568 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG7 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 30/249 reads (12%) | called by muse, mutect2, varscan2
- ATP10A | c.3772C>T p.P1258S | Missense Mutation (SNP) | VAF 73/434 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- ATP11C | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP13A4 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.516); called by muse, mutect2
- ATP5MF-PTCD1 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 44/452 reads (10%) | called by muse, mutect2, varscan2
- ATP6V0A4 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 100/442 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ATP8A1 | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ATXN2 | c.3372T>C p.I1124= (on ENST00000550104; = p.I964= on NM_002973.4) | Splice Region (SNP) | VAF 62/275 reads (23%) | called by muse, mutect2, varscan2
- B3GNTL1 | c.435T>A p.D145E | Missense Mutation (SNP) | VAF 133/499 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BHLHE41 | c.1322_1338del p.L441Pfs*53 | Frame Shift Del (DEL) | VAF 70/558 reads (13%) | called by mutect2, pindel
- BIRC6 | c.5084C>T p.P1695L | Missense Mutation (SNP) | VAF 48/407 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BNC1 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 124/433 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- BPTF | c.6589T>C p.S2197P | Missense Mutation (SNP) | VAF 48/349 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BRWD3 | c.4090G>A p.D1364N | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- BSPH1 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 87/293 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- C12orf43 | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- C16orf96 | c.873_895del p.E291Dfs*17 | Frame Shift Del (DEL) | VAF 68/562 reads (12%) | called by mutect2, pindel
- C1orf87 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 71/381 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- C3orf49 | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- C4orf17 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 61/415 reads (15%) | called by muse, mutect2, varscan2
- C5orf34 | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- C7orf57 | c.138T>G p.N46K | Missense Mutation (SNP) | VAF 30/635 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, mutect2
- CABP4 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 73/508 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1C | c.5989C>T p.H1997Y (on ENST00000399634 / NM_001167625.1; = p.H1926Y on NM_000719.7) | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CAMTA2 | c.2666C>T p.P889L | Missense Mutation (SNP) | VAF 82/446 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CAMTA2 | c.2665C>T p.P889S | Missense Mutation (SNP) | VAF 83/447 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAPRIN1 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CASC3 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 39/447 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.395); called by muse, mutect2
- CASR | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CBLL2 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 85/571 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CCBE1 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC102A | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 63/483 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- CD226 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 74/489 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- CD5L | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 33/416 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- CDHR2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP126 | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- CFAP92 | c.3296G>T p.G1099V | Missense Mutation (SNP) | VAF 70/397 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- CHL1 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRD | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CHRNA2 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 95/508 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIART | c.1038G>A p.W346* | Nonsense Mutation (SNP) | VAF 40/630 reads (6%) | called by muse, mutect2
- CLCN5 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 87/489 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CLMN | c.2609A>G p.H870R | Missense Mutation (SNP) | VAF 66/412 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNTNAP2 | c.3644G>A p.G1215E | Missense Mutation (SNP) | VAF 311/801 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- COBLL1 | c.2514T>G p.H838Q (on ENST00000392717; = p.H800Q on NM_014900.5) | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- COL11A1 | c.4499C>T p.P1500L | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- COL2A1 | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 93/476 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A3 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 54/399 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- COL4A5 | c.4367C>T p.S1456F | Missense Mutation (SNP) | VAF 92/585 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- COL5A2 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CORO2A | c.130A>G p.N44D | Missense Mutation (SNP) | VAF 96/536 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRISP3 | c.140C>T p.P47L (on ENST00000371159 / NM_001368123.1; = p.P29L on NM_006061.4) | Missense Mutation (SNP) | VAF 48/371 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CROCC2 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CSMD2 | c.4993C>T p.H1665Y | Missense Mutation (SNP) | VAF 124/450 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- CSNKA2IP | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- CSPG4 | c.5584G>T p.D1862Y | Missense Mutation (SNP) | VAF 153/610 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CXCR4 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 62/387 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CYP4F2 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CYRIA | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DACH1 | c.1424C>T p.P475L (on ENST00000619232 / NM_001366712.1; = p.P423L on NM_080759.6) | Missense Mutation (SNP) | VAF 55/306 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DEFB134 | c.133_134del p.S45* | Frame Shift Del (DEL) | VAF 38/363 reads (10%) | called by pindel, varscan2*
- DENND11 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 78/665 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, varscan2
- DENND2C | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 25/291 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHDH | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 96/229 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- DISP1 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 74/533 reads (14%) | called by muse, mutect2, varscan2
- DLGAP2 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 22/345 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- DMRTB1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 85/686 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- DNAH5 | c.11546G>A p.G3849D | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.037); called by muse, varscan2
- DNAH5 | c.2939C>T p.A980V | Missense Mutation (SNP) | VAF 38/351 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DNAH7 | c.2417G>A p.G806E | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- DND1 | c.261C>A p.F87L | Missense Mutation (SNP) | VAF 98/541 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DOCK3 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 32/347 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2
- DYSF | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 75/397 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- EPHA4 | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM151B | c.404T>A p.L135H | Missense Mutation (SNP) | VAF 59/409 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FAM161B | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 84/485 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- FAM171A1 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 65/416 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- FASN | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 74/516 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAT4 | c.9922G>A p.E3308K | Missense Mutation (SNP) | VAF 70/356 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FLG2 | c.6457G>A p.D2153N | Missense Mutation (SNP) | VAF 139/611 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FLOT1 | c.1244G>T p.S415I | Missense Mutation (SNP) | VAF 50/342 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- FMO3 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 27/339 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); called by muse, mutect2
- FN1 | c.4885G>A p.V1629I | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FPGT | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FREM1 | c.5183G>A p.G1728E | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- FREM2 | c.8508A>T p.E2836D | Missense Mutation (SNP) | VAF 73/411 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRMPD3 | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 77/533 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GABRB3 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 55/351 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- GAK | c.2475G>T p.E825D | Missense Mutation (SNP) | VAF 80/439 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GANC | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 39/298 reads (13%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAS2L2 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 76/588 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GBA3 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GCNA | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 59/373 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCNA | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 58/373 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCNT1 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 80/448 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GIMAP7 | c.644A>T p.Q215L | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GIMD1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2
- GLT8D2 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLYATL3 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 59/394 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1495A>G p.K499E | Missense Mutation (SNP) | VAF 71/810 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, varscan2
- GOLGA8H | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 60/451 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- GPR155 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GPR4 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 99/319 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GPR50 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 114/590 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- GRIK3 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 52/320 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIN2C | c.1107G>A p.W369* | Nonsense Mutation (SNP) | VAF 52/285 reads (18%) | called by muse, mutect2, varscan2
- GRK2 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- GRM2 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 83/399 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- GTF2IRD2B | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 137/547 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GUCY1A1 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GYPA | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HECTD4 | c.7435C>T p.R2479C | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- HMOX2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 81/424 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- HRG | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 64/452 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSF5 | c.1482T>A p.H494Q | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HSPA1L | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 81/524 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HUNK | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 97/568 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGDCC4 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 135/586 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- IGHV2-26 | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- IGSF10 | c.119_120insTT p.E40Dfs*10 | Frame Shift Ins (INS) | VAF 78/472 reads (17%) | called by mutect2, varscan2*
- IGSF10 | c.117_118del p.E40Gfs*31 | Frame Shift Del (DEL) | VAF 78/478 reads (16%) | called by mutect2, varscan2*
- IL18R1 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- IMPG1 | c.1398T>A p.D466E | Missense Mutation (SNP) | VAF 89/389 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- INPP5J | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 66/434 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- INSYN2B | c.587A>C p.E196A | Missense Mutation (SNP) | VAF 76/426 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IQGAP2 | c.4368-1G>A p.X1456_splice | Splice Site (SNP) | VAF 26/230 reads (11%) | called by muse, mutect2, varscan2
- IQSEC2 | c.1621G>A p.G541S (on ENST00000642864 / NM_001111125.3; = p.G336S on NM_015075.2) | Missense Mutation (SNP) | VAF 106/818 reads (13%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- JADE2 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 102/531 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- JADE3 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 58/385 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- KALRN | c.4684G>A p.A1562T | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- KBTBD13 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 142/610 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- KCNB2 | c.1975G>A p.G659R | Missense Mutation (SNP) | VAF 86/401 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- KCNH5 | c.667A>T p.I223F | Missense Mutation (SNP) | VAF 61/385 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- KIAA0513 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 45/268 reads (17%) | called by muse, mutect2, varscan2
- KIAA1217 | c.4598C>T p.P1533L | Missense Mutation (SNP) | VAF 71/381 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- KIAA1328 | c.1705C>T p.Q569* | Nonsense Mutation (SNP) | VAF 42/270 reads (16%) | called by muse, mutect2, varscan2
- KIAA1671 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 61/402 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIF12 | c.1780C>T p.P594S (on ENST00000640217; = p.P456S on NM_138424.1) | Missense Mutation (SNP) | VAF 69/436 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- KIF26A | c.4043C>T p.P1348L | Missense Mutation (SNP) | VAF 85/544 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIRREL2 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 179/586 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KRT10 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KRTAP9-1 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 88/446 reads (20%) | called by muse, varscan2
- LRCH2 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- LSM14B | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 77/512 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MACF1 | c.17029G>A p.E5677K (on ENST00000372915; = p.E3719K on NM_012090.5) | Missense Mutation (SNP) | VAF 42/315 reads (13%) | called by muse, mutect2, varscan2
- MAGEB16 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 86/615 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MAP1A | c.5329C>T p.P1777S | Missense Mutation (SNP) | VAF 100/528 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- MAP2K7 | c.894C>G p.D298E | Missense Mutation (SNP) | VAF 131/432 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.288); called by muse, varscan2
- MATN4 | c.1189G>A p.V397M (on ENST00000372754; = p.V356M on NM_003833.4) | Missense Mutation (SNP) | VAF 60/445 reads (13%) | PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MBD1 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 93/572 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MECOM | c.1528C>T p.P510S (on ENST00000468789 / NM_001105078.4; = p.P698S on NM_004991.4) | Missense Mutation (SNP) | VAF 55/379 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MESP2 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 147/653 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- METTL11B | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 144/579 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MGAM2 | c.5191A>G p.I1731V | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MICAL2 | c.4766C>T p.S1589F | Missense Mutation (SNP) | VAF 57/457 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- MKLN1 | c.830T>A p.V277D | Missense Mutation (SNP) | VAF 57/428 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MLKL | c.617G>A p.W206* | Nonsense Mutation (SNP) | VAF 64/433 reads (15%) | called by muse, mutect2, varscan2
- MPP3 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRGPRX2 | c.619G>T p.V207F | Missense Mutation (SNP) | VAF 83/437 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MRO | c.510T>G p.F170L | Missense Mutation (SNP) | VAF 57/380 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- MRPL38 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTNR1A | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 71/482 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC17 | c.4012C>T p.P1338S | Missense Mutation (SNP) | VAF 181/584 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MUC17 | c.8549C>T p.S2850F | Missense Mutation (SNP) | VAF 43/683 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); called by muse, mutect2
- MUC17 | c.12466C>T p.L4156F | Missense Mutation (SNP) | VAF 61/544 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- MUC17 | c.12973G>A p.G4325R | Missense Mutation (SNP) | VAF 197/487 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- MVD | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO10 | c.3253C>T p.P1085S | Missense Mutation (SNP) | VAF 84/561 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MYO18B | c.4660G>A p.E1554K | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MYRFL | c.1182G>A p.R394= | Splice Region (SNP) | VAF 25/254 reads (10%) | called by muse, mutect2
- NAV3 | c.5216C>T p.S1739F | Missense Mutation (SNP) | VAF 71/454 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBEA | c.8186C>T p.S2729F | Missense Mutation (SNP) | VAF 139/516 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NCAPG2 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 61/453 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NCKAP1L | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- NDST1 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 63/428 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- NEB | c.3496C>T p.H1166Y | Missense Mutation (SNP) | VAF 73/408 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, varscan2
- NET1 | c.371C>T p.T124I (on ENST00000355029 / NM_001047160.3; = p.T70I on NM_005863.5) | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- NEXMIF | c.2659A>T p.N887Y | Missense Mutation (SNP) | VAF 82/536 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- NEXMIF | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 88/531 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); called by muse, varscan2
- NFATC4 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 64/354 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP3 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 197/586 reads (34%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NLRP5 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 100/328 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- NNMT | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 69/341 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NOL6 | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 69/433 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- NOTCH2 | c.6221C>T p.T2074I | Missense Mutation (SNP) | VAF 77/523 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- NPIPB15 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 54/792 reads (7%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.771); called by muse, mutect2
- NPNT | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- NRP1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- NUTM2B | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- NUTM2B | c.2144C>T p.T715I | Missense Mutation (SNP) | VAF 105/972 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- NUTM2F | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NYX | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 97/705 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- OBP2A | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 56/430 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.442); called by muse, mutect2
- ODF3L2 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 63/393 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPN1LW | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 61/402 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- OR10C1 | c.253C>T p.H85Y (on ENST00000622521; = p.H83Y on NM_013941.3) | Missense Mutation (SNP) | VAF 117/768 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- OR10J1 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 98/443 reads (22%) | SIFT tolerated (0.99); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR2B2 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 74/424 reads (17%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- OR2L5 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2
- OR2T10 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 166/495 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- OR2T4 | c.432T>A p.F144L | Missense Mutation (SNP) | VAF 274/795 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR2T6 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 73/1068 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- OR4A8 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 61/348 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4C15 | c.380C>T p.S127L (on ENST00000314644; = p.S73L on NM_001001920.2) | Missense Mutation (SNP) | VAF 77/454 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- OR52E1 | c.302T>C p.F101S | Missense Mutation (SNP) | VAF 73/435 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- OR5BS1P | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 63/349 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OSER1 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 67/472 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- OSMR | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- OSMR | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 60/371 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OTOGL | c.6386C>T p.S2129F (on ENST00000547103; = p.S2120F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- OTUD5 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 68/423 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PABPN1L | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 97/491 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PACS2 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 76/393 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PACS2 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 49/304 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PAPPA | c.4570G>A p.D1524N | Missense Mutation (SNP) | VAF 58/385 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH1 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 59/459 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDH18 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 57/430 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PCDHA10 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 120/729 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- PCDHA8 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHAC2 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 57/384 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB1 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 62/490 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCLO | c.12098C>T p.S4033F | Missense Mutation (SNP) | VAF 60/493 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCLO | c.7499C>T p.T2500I | Missense Mutation (SNP) | VAF 185/610 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- PCSK5 | c.4340G>A p.G1447E | Missense Mutation (SNP) | VAF 81/465 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.327); called by muse, mutect2
- PDE6A | c.1045T>A p.Y349N | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PDPR | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 46/786 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- PDS5B | c.1694T>A p.V565E | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PDZD2 | c.7757A>G p.D2586G | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PDZD4 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 102/596 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PHF12 | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 74/481 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PKDREJ | c.5423C>T p.P1808L | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- POMT2 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R3E | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 119/599 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PPP4R3C | c.2444A>G p.E815G | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRB3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 43/393 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PRKDC | c.12121C>T p.R4041* | Nonsense Mutation (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
- PRKDC | c.4868T>G p.L1623R | Missense Mutation (SNP) | VAF 59/399 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRMT9 | c.1055A>G p.Y352C | Missense Mutation (SNP) | VAF 54/341 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRR14L | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PRSS41 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 67/447 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSG1 | c.44G>A p.W15* | Nonsense Mutation (SNP) | VAF 131/437 reads (30%) | called by muse, mutect2, varscan2
- PSME1 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 57/331 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PSPC1 | c.830_832delinsTT p.S277Ffs*41 | Frame Shift Del (DEL) | VAF 59/347 reads (17%) | called by pindel, varscan2*
- PTCHD3 | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPRF | c.2758C>T p.Q920* | Nonsense Mutation (SNP) | VAF 25/778 reads (3%) | called by muse, mutect2
- PXDNL | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2
- RAB44 | c.2210G>A p.G737E | Missense Mutation (SNP) | VAF 81/486 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- RANBP3 | c.1199A>G p.N400S (on ENST00000340578 / NM_007322.3; = p.N395S on NM_003624.3) | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RAPGEF3 | c.1844C>T p.P615L (on ENST00000389212; = p.P573L on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/376 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAPGEF6 | c.4138C>T p.P1380S | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- RASGRP2 | c.387G>A p.W129* | Nonsense Mutation (SNP) | VAF 54/317 reads (17%) | called by muse, mutect2, varscan2
- RELCH | c.1394T>G p.M465R | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RGPD3 | c.4703C>T p.S1568F | Missense Mutation (SNP) | VAF 39/602 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- RNF213 | c.5609C>T p.T1870I | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- RORC | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 100/424 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RPL15 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 45/358 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- RUNX2 | c.1454C>T p.P485L (on ENST00000371438; = p.P463L on NM_001015051.3) | Missense Mutation (SNP) | VAF 60/430 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SACS | c.4792C>T p.P1598S | Missense Mutation (SNP) | VAF 71/238 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SAMD4A | c.2108T>A p.M703K | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- SAMD7 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- SARM1 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 58/389 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC31B | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 80/417 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- SEMG2 | c.1261G>A p.G421R | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SF3B3 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 49/313 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SHC4 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SIGLEC5 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 106/402 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- SIM1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- SLC10A6 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SLC12A5 | c.2662G>A p.D888N (on ENST00000454036 / NM_001134771.2; = p.D865N on NM_020708.5) | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLC12A6 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 64/460 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC15A2 | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 52/339 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC16A5 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 103/491 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SLC17A7 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 144/451 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLC22A10 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC25A52 | c.49C>T p.H17Y (on ENST00000672005; = p.H7Y on NM_001034172.4) | Missense Mutation (SNP) | VAF 56/312 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC27A2 | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC27A2 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC4A9 | c.26A>T p.E9V | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- SLC6A2 | c.499T>A p.F167I | Missense Mutation (SNP) | VAF 80/448 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SLC7A4 | c.1694A>T p.Y565F | Missense Mutation (SNP) | VAF 49/313 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLC7A9 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 95/366 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLCO1B1 | c.1238T>G p.F413C | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLFN14 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 58/391 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK2 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 94/633 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA4 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 130/458 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- SNX19 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- SPAM1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 79/586 reads (13%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.1404T>A p.F468L | Missense Mutation (SNP) | VAF 94/595 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPDYE1 | c.518G>A p.W173* | Nonsense Mutation (SNP) | VAF 18/628 reads (3%) | called by muse, mutect2
- SPRY1 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- SPTA1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 89/388 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- SPTBN4 | c.260T>A p.V87E | Missense Mutation (SNP) | VAF 144/437 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SQOR | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 58/393 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SRRM2 | c.5578C>T p.P1860S | Missense Mutation (SNP) | VAF 79/551 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- SRRM4 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 52/310 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); called by muse, varscan2
- SSMEM1 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2
- STAR | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 19/356 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2
- STARD13 | c.2017G>A p.G673R (on ENST00000336934 / NM_001243476.3; = p.G555R on NM_052851.3) | Missense Mutation (SNP) | VAF 140/607 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- STARD8 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 80/660 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STK33 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 61/367 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- STYXL2 | c.3062T>G p.F1021C | Missense Mutation (SNP) | VAF 63/578 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- SUCO | c.190G>T p.G64* | Nonsense Mutation (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- SULT1B1 | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 24/186 reads (13%) | called by muse, mutect2, varscan2
- SYNE1 | c.14968G>A p.E4990K (on ENST00000367255 / NM_182961.4; = p.E4919K on NM_033071.3) | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE2 | c.16342C>T p.Q5448* | Nonsense Mutation (SNP) | VAF 67/410 reads (16%) | called by muse, mutect2, varscan2
- SZT2 | c.4481-1G>A p.X1494_splice (on ENST00000634258 / NM_001365999.1; = p.X1437_splice on NM_015284.4) | Splice Site (SNP) | VAF 39/348 reads (11%) | called by muse, mutect2, varscan2
- SZT2 | c.4481G>A p.G1494E (on ENST00000634258 / NM_001365999.1; = p.G1437E on NM_015284.4) | Missense Mutation (SNP) | VAF 39/351 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- TAS1R1 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 119/378 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.009); called by muse, varscan2
- TAS2R20 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TBC1D5 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBCCD1 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 62/333 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TCEAL4 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRKH | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 87/406 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- TECPR2 | c.791G>C p.G264A | Missense Mutation (SNP) | VAF 87/547 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TENM3 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 67/412 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TERT | c.2390C>T p.S797F | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TEX13D | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- THSD7B | c.4700C>T p.A1567V (on ENST00000272643; = p.A1565V on NM_001316349.2) | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.06); called by muse, varscan2
- TKTL2 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 64/403 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- TLE7 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- TMC5 | c.1250C>T p.S417F (on ENST00000396229 / NM_001105248.1; = p.S171F on NM_024780.5) | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEFF1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TMEM266 | c.1466A>G p.N489S | Missense Mutation (SNP) | VAF 128/483 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TMEM40 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 64/404 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNRC18 | c.2644_2663del p.W882Gfs*225 | Frame Shift Del (DEL) | VAF 126/542 reads (23%) | called by mutect2, pindel, varscan2
- TNRC6B | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 66/502 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- TNS3 | c.2761C>T p.Q921* | Nonsense Mutation (SNP) | VAF 155/573 reads (27%) | called by muse, mutect2, varscan2
- TOPBP1 | c.4352T>C p.V1451A | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
514 further variants in this file (47 protein-altering or splice-affecting, 425 silent, 42 other) are not listed here.
